MMRF case MMRF_1927 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/bb3d98d2-166b-40d6-9974-a1b71b047c68

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.0 years (24,477 days); ISS stage: III; Days to last known disease status: 1,078 days (3.0 years); Days to last follow up: 1,078 days (3.0 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 274 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 204 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 3 days; Days to treatment end: 148 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 175 days; Days to treatment end: 175 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 175 days; Days to treatment end: 204 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 300 days; Days to treatment end: 300 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 389 days (1.1 years); Days to treatment end: 472 days (1.3 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 473 days (1.3 years); Days to treatment end: 788 days (2.2 years).
   Treatment given: Therapeutic agents: Daratumumab + Dexamethasone + Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,072 days (2.9 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,078.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 7.43 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.658 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 10.5 mg/dL; Immunoglobulin G 111 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 13 µg/mL; Lactate Dehydrogenase 4.42 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 108 ×10⁹/L; Creatinine 119 µmol/L; Blood Urea Nitrogen 8.6 mmol/L; Calcium 1.85 mmol/L; Albumin 44.2 g/L; Total Protein 14 g/dL; Glucose 5.4 mmol/L.
- Day 97 (ECOG 0): M Protein 3.55 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.152 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.08 mg/dL; Immunoglobulin G 54.2 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 98 µmol/L; Blood Urea Nitrogen 5.7 mmol/L; Calcium 2.1 mmol/L; Albumin 40.5 g/L; Total Protein 9.6 g/dL; Glucose 5.4 mmol/L.
- Day 167 (ECOG 1): M Protein 1.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.597 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.631 mg/dL; Immunoglobulin G 16 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 3.08 µg/mL; Lactate Dehydrogenase 1.9 µkat/L; Hemoglobin 5.77 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 104 ×10⁹/L; Creatinine 83 µmol/L; Blood Urea Nitrogen 6.3 mmol/L; Calcium 1.92 mmol/L; Albumin 40.6 g/L; Total Protein 7.2 g/dL; Glucose 6.5 mmol/L.
- Day 265 (ECOG 1): M Protein 7.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.236 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.544 mg/dL; Immunoglobulin G 9.66 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 2.31 µg/mL; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 99 ×10⁹/L; Creatinine 100 µmol/L; Blood Urea Nitrogen 4 mmol/L; Calcium 2.29 mmol/L; Albumin 39.1 g/L; Total Protein 6.6 g/dL; Glucose 8 mmol/L.
- Day 354 (ECOG 1): M Protein 2.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.187 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.036 mg/dL; Immunoglobulin G 4.43 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 108 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 3.4 mmol/L; Calcium 2.2 mmol/L; Albumin 39.8 g/L; Total Protein 6.1 g/dL; Glucose 5 mmol/L.
- Day 438 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.745 mg/dL; Immunoglobulin G 4.72 g/L; Immunoglobulin A 4.72 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 109 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 5.2 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 6 g/dL; Glucose 5.4 mmol/L.
- Day 530 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.701 mg/dL; Immunoglobulin G 6.87 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 61 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 5.7 mmol/L; Calcium 2.29 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 4.3 mmol/L.
- Day 625 (ECOG 1): M Protein 6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.43 mg/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 1.46 g/L; Immunoglobulin M 0.3 g/L; Hemoglobin 8 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 85 ×10⁹/L; Creatinine 96 µmol/L; Blood Urea Nitrogen 5.7 mmol/L; Calcium 2.45 mmol/L; Albumin 42 g/L; Total Protein 7.2 g/dL; Glucose 6.3 mmol/L.
- Day 739 (ECOG 0): M Protein 6.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.43 mg/dL; Immunoglobulin G 9.86 g/L; Immunoglobulin A 1.55 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 2.1 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 75 ×10⁹/L; Creatinine 123 µmol/L; Blood Urea Nitrogen 6 mmol/L; Calcium 2.29 mmol/L; Albumin 39.1 g/L; Total Protein 7.3 g/dL; Glucose 8.5 mmol/L.
- Day 802 (ECOG 1): M Protein 5.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 1.27 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 4.62 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 86 ×10⁹/L; Creatinine 92 µmol/L; Blood Urea Nitrogen 5.3 mmol/L; Calcium 2.31 mmol/L; Albumin 38 g/L; Total Protein 7 g/dL; Glucose 7.1 mmol/L.
- Day 888 (ECOG 1): M Protein 5.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.679 mg/dL; Immunoglobulin G 9.49 g/L; Immunoglobulin A 0.97 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 132 ×10⁹/L; Creatinine 93 µmol/L; Blood Urea Nitrogen 4.7 mmol/L; Calcium 2.4 mmol/L; Albumin 43.8 g/L; Total Protein 7 g/dL; Glucose 4.5 mmol/L.
- Day 965 (ECOG 0): M Protein 6.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.957 mg/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 0.92 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 99 µmol/L; Calcium 2.51 mmol/L; Albumin 40 g/L; Total Protein 7.2 g/dL; Glucose 6.2 mmol/L.
- Day 1,073 (ECOG 2): M Protein 4.84 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 24.6 mg/dL; Immunoglobulin G 72.5 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 16.3 µg/mL; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 58 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 10.3 mmol/L; Calcium 2.27 mmol/L; Albumin 29 g/L; Total Protein 11.9 g/dL; Glucose 6.7 mmol/L.

Other clinical attributes
- Day 1: Weight: 84 kg; Height: 184 cm.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample MMRF_1927_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1927_1_PB_CD138pos: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
- Sample MMRF_1927_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
